Somatic mutation profile of tumor specimen C3L-05898-54 (aliquot CPT0344950002) from CPTAC case C3L-05898, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 79.4 years (28,998 days).
Specimen C3L-05898-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1af4e5d-59ed-4244-81d6-0fc2561cc9da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05898-50 (Buccal Cell Normal), aliquot CPT0344920005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6829032d-8317-43e9-a7bd-06866ae32590

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913491, COSV54054678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 285/657 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 63/141 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs77375493, CM123094, COSV67569051, COSV67571909; ClinVar: risk factor / pathogenic / likely pathogenic / not provided / affects; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IFNA6 | c.386T>G p.V129G | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.639); catalogued as COSV66506512; called by muse, mutect2, varscan2
- RAD51AP1 | c.986A>G p.N329S (on ENST00000228843 / NM_001130862.2; = p.N312S on NM_006479.5) | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs758683312; called by muse, mutect2, varscan2
- ZNF860 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 158/339 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs776070083, COSV64384577; called by muse, mutect2, varscan2
- IGSF11 | c.1205A>T p.H402L (on ENST00000393775 / NM_001015887.3; = p.H401L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/212 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PCDH18 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AVIL | c.2280T>A p.P760= | Silent (SNP) | VAF 67/171 reads (39%) | catalogued as COSV57680849; called by muse, mutect2, varscan2
- CREG1 | c.12A>C p.L4= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- CSMD2 | c.8340G>A p.P2780= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as rs762621710, COSV99596415; called by muse, mutect2, varscan2
- GUCY2F | c.2937T>C p.I979= | Silent (SNP) | VAF 68/151 reads (45%) | called by mutect2, varscan2
- NDNF | c.723G>A p.P241= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as rs375394141; called by muse, mutect2, varscan2
- SPAM1 | c.252C>T p.T84= | Silent (SNP) | VAF 62/117 reads (53%) | catalogued as rs759911125, COSV56149280, COSV99773201; called by muse, mutect2, varscan2
- ZNRF3 | c.1206C>T p.H402= (on ENST00000544604 / NM_001206998.2; = p.H302= on NM_032173.3) | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as rs1409054576; called by muse, mutect2, varscan2
- REV3L | c.139+10668A>T | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
